FM case AD6164 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/5bb492a4-8bf4-4a65-b151-75ec4b6f8d8a

Female, 44.2 years: Clear cell carcinoma (ICD-O-3 8310/3) of the kidney; primary biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
